Somatic mutation profile of tumor specimen TCGA-UZ-A9PU-01A (aliquot TCGA-UZ-A9PU-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b0e7c93-327f-4a0b-a4ae-972659e89350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PU-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PU-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68a3354a-deca-42ff-b63e-9292d113daf2

The open-access MAF lists 59 somatic variants for this specimen: 52 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 41, Frame Shift Del 9, Silent 7, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.3198C>G p.D1066E | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.388); catalogued as COSV100042301; called by muse, mutect2, varscan2
- ALMS1 | c.7270G>T p.G2424C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.414); catalogued as COSV100042302; called by muse, varscan2
- ALMS1 | c.7271G>T p.G2424V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV100042303; called by muse, varscan2
- ARRDC4 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.038); catalogued as COSV99164359; called by muse, mutect2, varscan2
- BAAT | c.498G>C p.L166F | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99408465; called by muse, mutect2, varscan2
- BMPR2 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as COSV101001466; called by muse, mutect2, varscan2
- CALCOCO1 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs545468025, COSV100017305; called by muse, mutect2, varscan2
- CDK4 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99225980; called by muse, mutect2, varscan2
- CLIP3 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1416236691, COSV99431024; called by muse, mutect2, varscan2
- CLUL1 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs770548099, COSV100620967; called by muse, mutect2, varscan2
- CPS1 | c.3756G>C p.L1252F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99242879; called by muse, mutect2, varscan2
- CYP1A2 | c.530A>C p.Q177P | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); catalogued as COSV100673888; called by muse, mutect2, varscan2
- FAM107A | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100723958; called by muse, mutect2, varscan2
- FLT1 | c.3786C>G p.D1262E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1156625069, COSV99154605; called by muse, mutect2, varscan2
- FOXP4 | c.827C>G p.T276S (on ENST00000307972 / NM_001012426.1; = p.T275S on NM_138457.3) | Missense Mutation (SNP) | VAF 105/127 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100332674; called by muse, mutect2, varscan2
- IL16 | c.3616C>G p.L1206V (on ENST00000302987 / NM_172217.5; = p.L505V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100250820; called by muse, mutect2, varscan2
- IL2 | c.145A>T p.N49Y | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99900763; called by muse, varscan2
- ITPR3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs916427217, COSV65413547; called by muse, mutect2, varscan2
- MAGEF1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100510962; called by muse, mutect2, varscan2
- MAPT | c.1748C>A p.S583* (on ENST00000262410 / NM_001377265.1; = p.S191* on NM_005910.5) | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | catalogued as COSV99290418; called by muse, varscan2
- NLRP1 | c.2573C>A p.A858D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99334018; called by muse, mutect2, varscan2
- NYAP2 | c.1647C>A p.S549R | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99796487; called by muse, mutect2, varscan2
- OR10K1 | c.749T>G p.V250G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99193494; called by muse, mutect2, varscan2
- PADI1 | c.907C>G p.P303A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100969086; called by muse, mutect2
- PANK4 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101015621; called by muse, mutect2
- PCLO | c.13539A>C p.L4513F | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100432007; called by muse, mutect2, varscan2
- PID1 | c.599T>A p.V200E (on ENST00000354069 / NM_001330156.1; = p.V198E on NM_017933.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100819625; called by muse, mutect2, varscan2
- PLXNA2 | c.4104C>G p.F1368L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100885413; called by muse, mutect2, varscan2
- POLR1A | c.1393A>C p.K465Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99807589; called by muse, mutect2, varscan2
- POT1 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1188122279, COSV62928251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR12 | c.2251G>C p.G751R (on ENST00000615927; = p.G1572R on NM_020719.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV101330658; called by muse, mutect2, varscan2
- SDAD1 | c.550A>C p.M184L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as COSV100668603; called by muse, mutect2, varscan2
- SLC2A9 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99304549; called by muse, mutect2, varscan2
- SLC40A1 | c.262A>G p.R88G | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs387907374, CM076533, COSV99656274; ClinVar: not provided; called by muse, mutect2, varscan2
- SPEN | c.4670C>T p.S1557F | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV101005199; called by muse, mutect2, varscan2
- TEX35 | c.120A>C p.E40D | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99274412; called by muse, mutect2, varscan2
- TSPOAP1 | c.166A>G p.R56G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99270959; called by muse, mutect2, varscan2
- UVRAG | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as COSV100638334; called by muse, mutect2, varscan2
- XIRP2 | c.8240A>G p.Q2747R (on ENST00000628543; = p.Q2922R on NM_152381.6) | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV54683234, COSV99742434; called by muse, mutect2, varscan2
- ZNF616 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs878875864, COSV100348308; called by muse, mutect2, varscan2
- ZWILCH | c.1744A>G p.M582V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs774261063, COSV100328607; called by muse, mutect2, varscan2
- CACNA1H | c.6702del p.T2235Qfs*27 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- DHX30 | c.3319_3325del p.V1107Sfs*12 (on ENST00000445061 / NM_138615.3; = p.V1068Sfs*12 on NM_014966.3) | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- FHL1 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMN1 | c.4138dup p.M1380Nfs*25 (on ENST00000616417 / NM_001277313.2; = p.M1157Nfs*25 on NM_001103184.4) | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- LCE4A | c.97del p.C33Afs*28 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | called by mutect2, pindel, varscan2
- NAA50 | c.290del p.L97* | Frame Shift Del (DEL) | VAF 130/529 reads (25%) | called by mutect2, pindel, varscan2
- NBEA | c.1389del p.E464Rfs*13 | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- NPEPL1 | c.235_241delinsTGCGC p.L79Cfs*112 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by pindel, varscan2*
- POLR3H | c.381_382del p.W127Cfs*32 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- SYNE2 | c.8757del p.K2921Rfs*22 | Frame Shift Del (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- ZNF256 | c.1198del p.L400Ffs*33 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- FOSL2 | c.663G>C p.V221= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99268323; called by muse, mutect2, varscan2
- HMCN1 | c.13116G>A p.E4372= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV99628650; called by muse, mutect2, varscan2
- KIAA2013 | c.1429C>T p.L477= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs779114878, COSV100927126; called by muse, mutect2, varscan2
- NRXN1 | c.1041A>G p.G347= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100454881; called by muse, mutect2, varscan2
- PTPRD | c.3816T>C p.G1272= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100644657; called by muse, mutect2, varscan2
- SNW1 | c.570T>C p.S190= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99834330; called by muse, mutect2, varscan2
- SYNE2 | c.18138C>T p.S6046= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs770053605, COSV100647514; called by muse, mutect2, varscan2
